FM case AD11969 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Other and unspecified major salivary glands.
https://portal.gdc.cancer.gov/cases/ac7bfd78-2db2-43ae-9be8-4025cdb45460

Female, 53.8 years: Carcinoma, NOS (ICD-O-3 8010/3) of the major salivary gland; primary biopsied or resected from the parotid gland. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
